CCDI case PBCGEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/13bc366d-df34-491c-aa48-032face17a0e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Angiomatoid fibrous histiocytoma: ICD-O-3 morphology code: 8836/1; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 14.2 years (5,173 days).

Biospecimens (3 samples)
- Sample 0DRKKA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRKKT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
